Gene-level copy-number profile of tumor specimen C3L-02627-04 (profiled together with C3L-02627-05) from CPTAC case C3L-02627, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 64.8 years (23,667 days).
Specimen C3L-02627-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2036d9d4-6193-40b6-96ee-c23ed49f057e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02627-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/4241ad70-0fa4-4fce-b368-94597ccf3c09

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 48; copy number 1: 3; copy number 2: 16,463; copy number 3: 815; copy number 4: 35,712; copy number 5: 1,150; copy number 6: 3,110; copy number 7: 385; copy number 8: 635; copy number 9: 8; copy number 10: 2; copy number 11: 18; copy number 12: 42.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:70,954,708–71,754,229, 4 genes (within-gene range 0–2): FOXP1, AC097634.4, FOXP1-AS1, MIR1284.
- chr5:86,884,231–87,412,930, 10 genes (within-gene range 0–2): AC091429.1, AC109492.1, MIR4280HG, RN7SKP34, MIR4280, LINC01949, RASA1, RN7SL629P, RNU6-606P, CCNH.
- chr9:21,638,285–22,029,594, 11 genes (within-gene range 0–2): H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–21,996,013, 1 gene (within-gene range 0–2): AL449423.1.
- chr9:40,121,962–40,153,147, 3 genes: CDRT15P14, AL773545.1, AL773545.2.
- chr9:41,292,887–41,648,035, 10 genes: MYO5BP1, AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70, RN7SL565P, AL591926.7, AL591926.6, AL591926.5.
- chr13:72,782,133–73,077,541, 4 genes: PIBF1, RNU6-79P, PSMD10P3, KLF5.
- chr21:44,994,362–45,004,727, 2 genes: LINC00165, PICSAR.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 70 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:9,621,377–9,712,378, 2 genes, copy number 9 (within-gene range 7–9): AC026787.1, TAS2R1.
- chr8:39,106,990–39,417,378, 4 genes, copy number 11: ADAM32, RPL3P10, AC105185.1, ADAM5.
- chr8:140,505,813–140,638,283, 6 genes, copy number 9: AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD.
- chr8:145,047,860–145,066,685, 2 genes, copy number 10: AC139103.1, C8orf33.
- chr17:64,319,415–65,227,703, 42 genes, copy number 12: PECAM1, Y_RNA, AC234063.1, MILR1, POLG2, ATP5MFP4, DDX5, MIR3064, MIR5047, CEP95, SMURF2, AC009994.1, MICOS10P2, ARHGAP27P1-BPTFP1-KPNA2P3, KPNA2P3, AC132812.1, BPTFP1, AC103810.3, PLEKHM1P1, MIR6080, MIR4315-2, RNU7-115P, AC103810.9, LRRC37A3, RN7SL404P, AC103810.6, AC103810.7, AC103810.2, AC103810.5, RDM1P4, AC103810.1, AC103810.4, AC037487.4, AC103810.8, AC037487.1, AC037487.3, SLC16A6P1, AMZ2P1, GNA13, AC037487.2, RGS9, AC060771.1.
- chr17:72,645,949–73,092,712, 1 gene, copy number 11 (within-gene range 8–11): SLC39A11.
- chr17:72,818,836–73,312,005, 13 genes, copy number 11: AC080037.1, AC011120.1, ATG12P1, POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
